Somatic mutation profile of tumor specimen TARGET-40-PALIXF-01A (aliquot TARGET-40-PALIXF-01A-01D) from TARGET case TARGET-40-PALIXF, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 13.6 years (4,978 days).
Specimen TARGET-40-PALIXF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c808dd06-69b4-4243-a6f7-596b6be21be0.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PALIXF-11A (Solid Tissue Normal), aliquot TARGET-40-PALIXF-11A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4f1cb84-2595-4857-ad2c-fdd459a48ee9

The open-access MAF lists 1 somatic variant for this specimen: 1 silent.
By variant classification: Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM7A | c.1251G>C p.L417= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
